Somatic mutation profile of tumor specimen TCGA-97-7553-01A (aliquot TCGA-97-7553-01A-21D-2036-08) from TCGA case TCGA-97-7553, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.9 years (21,518 days).
Specimen TCGA-97-7553-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b25916cd-80ce-49fc-874c-2d26e5db6d0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-7553-10A (Blood Derived Normal), aliquot TCGA-97-7553-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd852a09-d4fc-48a7-a58f-5b515420af36

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 2, In Frame Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- NF1 | c.6854dup p.Y2285* (on ENST00000358273 / NM_001042492.3; = p.Y2264* on NM_000267.3) | Nonsense Mutation (INS) | VAF 34/261 reads (13%) | catalogued as rs876657715, CI1311425, CI1411405, CI962317, COSV99049873; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 19/127 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP8B3 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs745619434, COSV59542722; called by muse, mutect2, varscan2
- BTBD9 | c.1469A>G p.D490G | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58425915; called by muse, mutect2, varscan2
- CAB39L | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100759458; called by muse, mutect2
- DCLRE1A | c.1403C>A p.P468H | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV63748718; called by muse, mutect2, varscan2
- DSP | c.4895A>T p.D1632V | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV65792711; called by muse, mutect2
- DST | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs183558657, COSV56808337; called by muse, mutect2
- EIF4G1 | c.4492C>T p.R1498* (on ENST00000346169 / NM_198241.3; = p.R1303* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 10/267 reads (4%) | catalogued as COSV59990986; called by muse, mutect2
- FAT2 | c.7864T>C p.Y2622H | Missense Mutation (SNP) | VAF 93/595 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270214144, COSV55819683; called by muse, mutect2, varscan2
- GALP | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 20/136 reads (15%) | catalogued as COSV61999959; called by muse, mutect2
- HUS1 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 28/205 reads (14%) | catalogued as COSV51839475; called by muse, mutect2, varscan2
- INSL5 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs137866143; called by muse, mutect2
- IQSEC3 | c.1462G>A p.V488I (on ENST00000538872 / NM_001170738.2; = p.V185I on NM_015232.1) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV58284848; called by muse, mutect2, varscan2
- KCNK9 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1321749969, COSV57281720; called by muse, mutect2
- KIF21B | c.2085G>T p.M695I | Missense Mutation (SNP) | VAF 75/433 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV59757726; called by muse, mutect2, varscan2
- LRFN2 | c.2317G>T p.G773W | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV57823869, COSV57827363; called by muse, mutect2, varscan2
- MPEG1 | c.803C>A p.S268* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV57089641, COSV57090751; called by muse, mutect2
- MS4A14 | c.1169C>A p.T390K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV55734888; called by muse, mutect2
- NBEA | c.137G>T p.R46M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV59783949; called by mutect2, varscan2
- PDLIM2 | c.248C>G p.S83C (on ENST00000397760; = p.S333C on NM_021630.6) | Missense Mutation (SNP) | VAF 50/335 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV56132758; called by muse, mutect2, varscan2
- PDLIM2 | c.380C>T p.S127F (on ENST00000397760; = p.S377F on NM_021630.6) | Missense Mutation (SNP) | VAF 72/485 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs977448506, COSV56132297; called by muse, mutect2, varscan2
- PIP4P2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764284578, COSV53437554; called by muse, mutect2
- RB1 | c.861+1G>A p.X287_splice | Splice Site (SNP) | VAF 11/114 reads (10%) | catalogued as CS0910389, COSV57298588, COSV57307382; called by muse, mutect2
- SELE | c.800C>G p.T267S | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.451); catalogued as COSV60975410; called by muse, mutect2, varscan2
- SLC29A2 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60803321; called by muse, mutect2
- SPSB1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 79/565 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100049363, COSV60163197; called by muse, mutect2, varscan2
- TMEM150B | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 69/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58593725; called by muse, mutect2, varscan2
- TRPM2 | c.4498G>A p.G1500R | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs966021909, COSV100308875, COSV55969658; called by muse, mutect2, varscan2
- WNT2B | c.242G>A p.R81Q (on ENST00000369684 / NM_024494.3; = p.R62Q on NM_004185.4) | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as rs776777214, COSV56674149; called by muse, mutect2, varscan2
- ZAN | c.7867C>T p.R2623W | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs766670328, COSV61809080; called by muse, mutect2, varscan2
- ZFHX4 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50797479; called by muse, mutect2, varscan2
- ZNF175 | c.1043C>A p.S348* | Nonsense Mutation (SNP) | VAF 45/280 reads (16%) | catalogued as COSV51795584; called by muse, mutect2, varscan2
- MBNL1 | c.277del p.M93Wfs*10 | Frame Shift Del (DEL) | VAF 42/257 reads (16%) | called by mutect2, pindel, varscan2
- OR5W2 | c.346_373del p.S116Pfs*21 | Frame Shift Del (DEL) | VAF 24/288 reads (8%) | called by mutect2, pindel
- PPME1 | c.769_775del p.E257Kfs*10 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- RASGEF1C | c.958_987+4del p.X320_splice | Splice Site (DEL) | VAF 36/386 reads (9%) | called by mutect2, pindel
- SCIN | c.2079_2081del p.I694del (on ENST00000297029 / NM_001112706.3; = p.I447del on NM_033128.3) | In Frame Del (DEL) | VAF 30/282 reads (11%) | called by pindel, varscan2
- ZKSCAN2 | c.960_977del p.S320_W325del | In Frame Del (DEL) | VAF 39/312 reads (13%) | called by mutect2, pindel
- ADAMTS10 | c.1326C>T p.T442= | Silent (SNP) | VAF 52/314 reads (17%) | catalogued as COSV54354848; called by muse, mutect2, varscan2
- CALML6 | c.519G>A p.T173= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs1180598909, COSV57069389; called by muse, mutect2
- GBX1 | c.1083C>T p.A361= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV52547556; called by muse, mutect2
- IL17RD | c.1461C>T p.D487= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as rs1335167075, COSV56337999; called by muse, mutect2
- KCNG2 | c.711C>A p.S237= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV60266553, COSV60267859; called by muse, mutect2, varscan2
- LACTB2 | c.396T>G p.T132= | Silent (SNP) | VAF 24/402 reads (6%) | catalogued as rs761049529; called by muse, mutect2
- MEFV | c.366C>T p.D122= | Silent (SNP) | VAF 32/163 reads (20%) | catalogued as rs1407541437, COSV54822033; called by muse, mutect2, varscan2
- MFSD8 | c.681G>A p.L227= | Silent (SNP) | VAF 22/211 reads (10%) | catalogued as COSV56551166; called by muse, mutect2, varscan2
- NCKAP1L | c.1051C>T p.L351= | Silent (SNP) | VAF 33/398 reads (8%) | catalogued as COSV53206808; called by muse, mutect2
- WASHC2A | c.3192A>T p.G1064= | Silent (SNP) | VAF 57/446 reads (13%) | catalogued as COSV99254442; called by muse, mutect2, varscan2
- WASHC2C | c.3153G>A p.Q1051= (on ENST00000336378; = p.Q1030= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 55/434 reads (13%) | called by muse, mutect2, varscan2
- COPS9 | chr2:240126599 C>T | 3'Flank (SNP) | VAF 45/297 reads (15%) | catalogued as COSV56228157; called by muse, mutect2, varscan2
